TCGA case TCGA-CH-5751 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/721e76d0-4b1d-4e78-adb8-1344b8030062

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 68 years; Vital status: Alive.

Diagnoses (2)
1. Acinar cell carcinoma (the primary disease): ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 68.3 years (24,957 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC clinical M: M0; AJCC pathologic T: T4; AJCC pathologic N: N1; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 10.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 3; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide + Leuprolide Acetate; Days to treatment start: 122 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Zoledronic Acid; Days to treatment start: 245 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Acinar cell carcinoma), site: Bone, NOS. Age at diagnosis: 69.3 years (25,322 days); Days to diagnosis: 365 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 92 (initial diagnosis): Days to imaging: 92 days; Imaging type: MRI; Imaging findings: Equivocal.
- Day 92 (initial diagnosis): Days to imaging: 92 days; Imaging type: Bone Scan, NOS; Imaging result: Indeterminate.
- Day 92 (initial diagnosis): Days to imaging: 92 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: Equivocal.
- Day 365 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 365 days (1.0 years).
- Days to follow up: 1,065 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,065 days (2.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.01 ng/mL (day 1,004).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CH-5751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-CH-5751-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CH-5751-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CH-5751-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CH-5751-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Biochemical recurrence indicator: No.
- Stage record, Psa: PSA most recent results: 0.01.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 5.
- Drug treatment 2: Pharmaceutical therapy drug name: Leuprorelin.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; New tumor event type: Distant Metastasis; New tumor event site: Bone; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Progression after hormone treatment: Yes; Progression after hormone treatment type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,065 days; disease-specific survival: no event (censored), 1,065 days; disease-free interval: event (new tumor event after initially disease-free), 365 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 365 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CH-5751-01A-11D-1574-01): tumor purity 0.54, ploidy 2.02, whole-genome doublings 0.
